CPTAC case C3N-09075 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/737ba428-f248-4bf5-af78-076bd15dcfac

Demographics
Sex at birth: male; Race: white; Year of birth: 1964; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 58.0 years (21,170 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T3b; AJCC pathologic N: N1b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 371 days (1.0 years); Progression or recurrence: no; Days to last follow up: 371 days (1.0 years); Tumor focality: Unifocal; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >2.0-4.0 mm; Greatest tumor dimension: 3 cm; Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 33; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (1 entry)
- Days to follow up: 371 days (1.0 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 12.3; Cigarettes per day: 7; Tobacco smoking onset year: 1986; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-09075-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -26 days; Initial weight: 43 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-09075-21: Section location: Lymph node; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3N-09075-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -26 days; Initial weight: 29 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-09075-22: Section location: Lymph node; Percent tumor nuclei: 70; Percent necrosis: 0.
- Sample C3N-09075-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -26 days; Initial weight: 57 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-09075-24: Section location: Lymph node; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3N-09075-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -26 days; Method of sample procurement: Blood Draw.
